Gene-level copy-number profile of tumor specimen TCGA-XE-AAO9-01A from TCGA case TCGA-XE-AAO9, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 23.5 years (8,600 days).
Specimen TCGA-XE-AAO9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05c989c8-db52-4153-9f03-1ed9c2b1517c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AAO9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,753 have no estimate.
https://portal.gdc.cancer.gov/files/b823b756-3819-448a-b4f7-f9c0de735dbf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 187; copy number 2: 1,983; copy number 3: 3,237; copy number 4: 19,523; copy number 5: 13,288; copy number 6: 12,373; copy number 7: 4,319; copy number 8: 2,609; copy number 9: 282; copy number 10: 553.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 835 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 10 (within-gene range 6–10): AL627309.1.
- chr1:131,025–135,895, 2 genes, copy number 10: CICP27, AL627309.6.
- chr5:17,585,162–17,635,053, 14 genes, copy number 9–10: TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14.
- chr8:112,222,928–113,436,939, 4 genes, copy number 9 (within-gene range 8–9): CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:113,432,224–113,433,129, 1 gene, copy number 9: AC055788.2.
- chr12:66,767–23,188,807, 613 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr12:24,810,024–27,781,067, 73 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr12:30,454,919–34,058,745, 90 genes, copy number 9 (broad region; genes not listed).
- chr15:21,298,233–21,325,241, 1 gene, copy number 9 (within-gene range 8–9): AC068446.2.
- chr15:21,328,380–21,752,710, 30 genes, copy number 9: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1.
- chr21:18,857,779–19,134,423, 6 genes, copy number 10: PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1.

Autosomal genes at a single copy (total copy number 1): 187. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
